Surgical pathology report (de-identified scan), TCGA case TCGA-ER-A19H, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Pittsburgh, specimen TCGA-ER-A19H-06A (Metastatic).

PATIENT HISTORY:

No clinical history is given.

PRE-OP DIAGNOSIS: Melanoma right chest

POST-OP DIAGNOSIS: Same

PROCEDURE: Wide excision chest melanoma and right axillary dissection

Site code: Chest wall, subcutaneous tissue C49.3

**ADDENDA:****Addendum**

Immunostains reveal tumor to be strongly positive with S-100 and Tyrosinase and is negative for Pankeratin. The results are in keeping with the diagnosis of metastatic melanoma.

FINAL DIAGNOSIS:**PART 1: SKIN AND SOFT TISSUE, RIGHT CHEST WALL, MELANOMA WIDE EXCISION -**

- A. MULTIPLE FOCI OF METASTATIC MELANOMA IN SKIN, SUBCUTANEOUS TISSUE AND POSSIBLE LYMPH NODE.
- B. MODERATE PERIPHERAL TUMOR INFILTRATING LYMPHOCYTES PRESENT. NO NECROSIS SEEN.
- C. SKIN MARGINS FREE.

PART 2: NEW INFERIOR MARGIN RESECTION -

FIBROFATTY TISSUE NEGATIVE FOR TUMOR.

**PART 3: SOFT TISSUE, LYMPH NODES, AXILLARY CONTENTS, RIGHT AXILLARY LYMPHADENECTOMY -
NINETEEN LYMPH NODES FREE OF TUMOR.****COMMENT:**The current tumor is amelanotic and pleomorphic and histologically compatible with melanoma. A prior lung biopsy interpreted as melanoma ~~was~~ was positive for melanoma markers. Some stains will be repeated and reported as addendum.

HI/AA Discrepancy		

Source: NCI Genomic Data Commons file 31d97481-229f-4e16-8a92-e98f88bd77e9 (TCGA-ER-A19H.8C9DBA9E-E8F5-4080-938D-B58F675461ED.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).